Somatic mutation profile of tumor specimen PCProject_0041_T1_WES (aliquot PCProject_0041_T1_WES_1) from CMI case PCProject_0041, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 85.9 years (31,367 days).
Specimen PCProject_0041_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ff603b2-b67a-4b71-b0fb-687eaf937d55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0041_SALIVA (Saliva), aliquot PCProject_0041_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42b937c9-906e-48bc-b523-bac39bfeefdf

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 5, 3'UTR 3, Intron 3, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP15 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.47); catalogued as rs748925321; called by muse, mutect2, varscan2
- CACNA1A | c.5653C>T p.R1885W | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746460335, COSV64198632, COSV64206275; called by muse, mutect2, varscan2
- CSPG5 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs142769230; called by muse, mutect2, varscan2
- FPR1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs186613919; called by muse, mutect2, varscan2
- GABRB2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99195911; called by muse, mutect2, varscan2
- HCAR2 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs931357507; called by muse, mutect2, varscan2
- MVP | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.073); catalogued as rs369258031; called by muse, mutect2, varscan2
- NUTM1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs746914938, COSV61548343; called by muse, mutect2, varscan2
- PTPRN2 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 102/478 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs199954744, COSV67038294; called by muse, mutect2, varscan2
- RHBDF2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 132/588 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs763172645; called by muse, mutect2, varscan2
- SHANK1 | c.2049G>A p.A683= | Splice Region (SNP) | VAF 60/154 reads (39%) | catalogued as rs1362825399, COSV53252866; called by muse, mutect2, varscan2
- TMEM63C | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs202241964, COSV53607413; called by muse, mutect2
- ZNF646 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | catalogued as rs1020631589, COSV56213531; called by muse, mutect2, varscan2
- APOBR | c.1474A>C p.S492R (on ENST00000431282; = p.S501R on NM_018690.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by mutect2, varscan2
- GPR21 | c.486_493del p.P163Ffs*82 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- GSX2 | c.46T>G p.S16A | Missense Mutation (SNP) | VAF 85/409 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPL | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KMT2D | c.15209A>G p.Y5070C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5D18 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB12 | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PHOX2A | c.467_472del p.G156_A157del | In Frame Del (DEL) | VAF 101/469 reads (22%) | called by mutect2, pindel, varscan2
- RD3 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SATB1 | c.1060dup p.S354Kfs*2 | Frame Shift Ins (INS) | VAF 43/153 reads (28%) | called by mutect2, pindel, varscan2
- TTC7B | c.2076G>C p.W692C | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP15 | c.2030A>G p.N677S (on ENST00000280377 / NM_001351159.2; = p.N648S on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- VPS9D1 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY7 | c.2685C>T p.C895= | Silent (SNP) | VAF 46/243 reads (19%) | catalogued as rs765862916; called by muse, mutect2, varscan2
- CTDSPL | c.495G>A p.V165= (on ENST00000273179 / NM_001008392.2; = p.V154= on NM_005808.3) | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- DCAF5 | c.1575G>A p.L525= | Silent (SNP) | VAF 49/193 reads (25%) | called by muse, mutect2, varscan2
- MEIS2 | c.138C>T p.H46= (on ENST00000561208 / NM_170675.5; = p.H33= on NM_002399.3) | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as rs760859088, COSV54931169; called by muse, mutect2, varscan2
- SLC6A19 | c.1020C>T p.N340= | Silent (SNP) | VAF 171/658 reads (26%) | catalogued as COSV58669805; called by muse, mutect2, varscan2
- AL137230.1 | n.502+1740T>C | Intron (SNP) | VAF 8/92 reads (9%) | catalogued as rs889798395; called by muse, mutect2
- CRB2 | c.1054+1174G>A | Intron (SNP) | VAF 37/127 reads (29%) | catalogued as rs765126978; called by muse, mutect2, varscan2
- FAM161A | c.*800C>A | 3'UTR (SNP) | VAF 7/51 reads (14%) | catalogued as rs1347758191; called by muse, varscan2
- NEIL1 | c.435-810G>A | Intron (SNP) | VAF 15/152 reads (10%) | called by muse, varscan2
- NLGN4Y | c.*1039G>C | 3'UTR (SNP) | VAF 25/198 reads (13%) | catalogued as rs914603689, COSV104410747; called by muse, varscan2
- PSG6 | c.*15A>G | 3'UTR (SNP) | VAF 6/32 reads (19%) | catalogued as rs1227315920; called by mutect2, varscan2
